MMRF case MMRF_1784 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/53f96aa4-cc38-43b2-babb-a758c5db6b63

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.5 years (22,099 days); Days to last known disease status: 1,115 days (3.1 years); Days to last follow up: 1,115 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 75 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 77 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 204 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -40: M Protein 3.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 114 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.21 mg/dL; Immunoglobulin G 2.38 g/L; Immunoglobulin A 51.4 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 292 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.4 mmol/L; Albumin 33 g/L; Total Protein 9.3 g/dL; Glucose 4.73 mmol/L.
- Day 79 (ECOG 1): M Protein 0.2 g/dL; Immunoglobulin G 5.43 g/L; Immunoglobulin A 1.94 g/L; Immunoglobulin M 1.02 g/L; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 8.2 mmol/L.
- Day 148 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 2.42 g/L; Immunoglobulin M 0.555 g/L; Lactate Dehydrogenase 5 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 2.17 ×10⁹/L; Platelets 361 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 6.66 mmol/L.
- Day 204 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 2.13 g/L; Immunoglobulin M 0.298 g/L; Lactate Dehydrogenase 3.88 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 365 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7.8 g/dL; Glucose 7.15 mmol/L.
- Day 304 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 2.49 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.39 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 4.73 mmol/L.
- Day 452: Creatinine 91.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.05 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 4.84 mmol/L.
- Day 575: M Protein 0 g/dL; Hemoglobin 7.44 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 0.85 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 5.45 mmol/L.
- Day 680: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3 mg/dL; Hemoglobin 7.75 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.97 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 6.44 mmol/L.
- Day 772: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.3 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 3.56 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 5.28 mmol/L.
- Day 840: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.3 mg/dL; Hemoglobin 7.5 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.22 ×10⁹/L; Platelets 93 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 5.78 mmol/L.
- Day 931: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.13 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.61 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 4.51 mmol/L.
- Day 1,022: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.51 mg/dL; Immunoglobulin G 9.38 g/L; Immunoglobulin A 3.36 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.79 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.
- Day 1,115: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.68 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 3.85 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.65 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day -40: Weight: 100 kg; Height: 166 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1784_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -40 days.
- Sample MMRF_1784_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -40 days.
